Somatic mutation profile of tumor specimen TARGET-10-PATDGZ-09A (aliquot TARGET-10-PATDGZ-09A-01D) from TARGET case TARGET-10-PATDGZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (937 days).
Specimen TARGET-10-PATDGZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3da55a9-432c-4728-b15c-5e602c7c5a5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDGZ-14A (Bone Marrow Normal), aliquot TARGET-10-PATDGZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ce796d2-1bcd-4661-bf0a-234fa4583150

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 2, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52193595; called by muse, mutect2, varscan2
- ADAM29 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.29); catalogued as rs1279168247, COSV63659947; called by muse, mutect2, varscan2
- ALPI | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs779020997, COSV55013286; called by muse, mutect2, varscan2
- BDNF | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59232962; called by muse, mutect2, varscan2
- CIBAR2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as rs775012665, COSV73320530; called by muse, mutect2, varscan2
- DPF3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as rs533714896, COSV63498537; called by muse, mutect2, varscan2
- GFY | c.718A>C p.T240P | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV54527804; called by muse, mutect2, varscan2
- LRP4 | c.3062C>T p.P1021L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as CD148549, COSV66133851; called by muse, mutect2, varscan2
- MGRN1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765127125, COSV52147972; called by muse, mutect2, varscan2
- MUC5AC | c.15187T>G p.C5063G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611456; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- PHF6 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 23/26 reads (88%) | catalogued as COSV59699190; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- URB2 | c.3079A>T p.T1027S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV50981052, COSV50992657; called by muse, mutect2, varscan2
- ZSCAN20 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs751311263, COSV63681455; called by muse, mutect2, varscan2
- RHOA | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- FAM220A | c.210C>T p.S70= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs763859545; called by muse, mutect2, varscan2
- KRTAP8-1 | c.156C>T p.F52= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs201803377, COSV61597805; called by muse, mutect2, varscan2
- NPC1 | c.1350C>T p.I450= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs368945671, COSV52579864; called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084535 C>T | 5'Flank (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2
- CLCN3 | c.161-19622T>C | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- GRM8 | c.727+48408C>T | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs375234833; called by muse, mutect2, varscan2
- SNORD64 | chr15:24987030 G>A | 3'Flank (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
